Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040030-09A.1 (aliquot TARGET-15-SJMPAL040030-09A.1-01D) from TARGET case TARGET-15-SJMPAL040030, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,931 days).
Specimen TARGET-15-SJMPAL040030-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26ada370-8fa8-4654-9adb-8707298c725f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040030-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040030-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/198eef1c-4e57-425e-9aa7-ccd4c521f26d

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 15/133 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 69/405 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HMCN2 | c.13760C>T p.S4587L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs1315283512, COSV56739966; called by muse, mutect2, varscan2
- BNC2 | c.275del p.F92Sfs*26 | Frame Shift Del (DEL) | VAF 16/198 reads (8%) | called by mutect2, pindel
- CNTNAP2 | c.3101A>G p.D1034G | Missense Mutation (SNP) | VAF 144/343 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FEV | c.187G>T p.A63S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2
- HLF | c.114C>A p.D38E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- LRP1 | c.7315C>T p.R2439W | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NCOA4 | c.315dup p.L106Tfs*26 | Frame Shift Ins (INS) | VAF 11/107 reads (10%) | called by mutect2, pindel, varscan2
- TRDN | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NECTIN3-AS1 | n.1172+59G>A | Intron (SNP) | VAF 7/67 reads (10%) | catalogued as rs1429250420; called by muse, mutect2, varscan2
